Somatic mutation profile of tumor specimen TARGET-30-PAVEZM-01A (aliquot TARGET-30-PAVEZM-01A-01D) from TARGET case TARGET-30-PAVEZM, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 6.9 years (2,517 days).
Specimen TARGET-30-PAVEZM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9948099f-d729-47b1-adbc-9a6e36ee3942.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAVEZM-10A (Blood Derived Normal), aliquot TARGET-30-PAVEZM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0f8ebaa-2d8f-4df2-9038-b5e82087eaca

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.9112C>T p.Q3038* | Nonsense Mutation (SNP) | VAF 68/134 reads (51%) | catalogued as COSV53739959; called by muse, mutect2, varscan2
- SLC6A12 | c.893G>T p.C298F | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62885898; called by muse, mutect2, varscan2
